Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1O5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1O5-01A (Primary Tumor).

[page 1 of 3]
106-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 2/24/11 JH

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, bilateral ovaries and fallopian tubes;
hysterectomy and
bilateral salpingo-oophorectomy: FIGO grade I (of III)
endometrial
adenocarcinoma, endometrioid type, arising in a background
of
complex hyperplasia with atypia, forming an exophytic mass
(2.8 x
2.5 x 1.9 cm) located in the anterior uterine wall. The
tumor
invades 0.2 cm into the myometrium (total wall thickness
2.4 cm).
The tumor does not involve the endocervix and the cervix
is
unremarkable. Lymphovascular space invasion is not
identified.
Multiple (2) intramural leiomyomata ranging in size from
2.2 cm to
3.5 cm in greatest dimension are identified. The
bilateral ovaries
and fallopian tubes are without diagnostic abnormality.

B. Lymph nodes, right pelvic, lymphadenectomy: Multiple
(17) right
pelvic lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, lymphadenectomy: Multiple
(3) left
pelvic lymph nodes are negative for tumor.

With available surgical materials, [AJCC pT1aN0] (7th
edition, 2010).

This final pathology report is based on the
gross/macrosopic
examination and the frozen section histologic evaluation
of the

[page 2 of 3]
specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right fallopian tube and ovary"

is a 176.0 gram uterus with attached bilateral tubes and ovaries.

The uterine serosa is smooth. There is a 2.8 x 2.5 x 1.9 cm

exophytic mass in the left anterior wall of the endometrial cavity

grossly invades 0.2 cm to the myometrium. The myometrial thickness

is 2.4 cm. There are multiple (2) uterine intramural leiomyomas,

ranging in size from 2.2 cm to 3.5 cm.

There is a 1.1 x 0.5 x 0.3 cm right ovary with a ragged outer

surface and a solid cut surface with a 5.5 x 0.6 cm right fallopian

tube which is unremarkable. There is a 1.5 x 0.6 x 0.3 cm left ovary

with a ragged outer surface and a solid cut surface with a 6.5 x 0.5

cm left fallopian tube which is unremarkable.

Representative

sections submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 6.8 x 5.0

x 1.7 cm aggregate of adipose and lymphatic tissue. Lymph nodes

submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 7.1 x 4.5

[page 3 of 3]
x 1.2 cm aggregate of adipose and lymphatic tissue. Lymph
nodes
submitted.

Source: NCI Genomic Data Commons file 8596aa45-3577-486f-8f9a-fdf4e1917416 (TCGA-D1-A1O5.F8BEE46E-D0C9-4977-B1C3-DA87AF089B6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).